Somatic mutation profile of tumor specimen TCGA-DD-A114-01A (aliquot TCGA-DD-A114-01A-11D-A12Z-10) from TCGA case TCGA-DD-A114, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 42.2 years (15,410 days).
Specimen TCGA-DD-A114-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 655d70f1-5974-47b2-8ef8-9af0dbd7a998.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A114-10A (Blood Derived Normal), aliquot TCGA-DD-A114-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/139a2d9b-062c-4390-be2a-00dc4ede93f8

The open-access MAF lists 111 somatic variants for this specimen: 85 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 24, Nonsense Mutation 9, Frame Shift Del 4, Splice Site 2, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1959dup p.V654Sfs*14 | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | catalogued as rs1566234123; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 31/149 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ALDH1L2 | c.320T>C p.F107S | Missense Mutation (SNP) | VAF 58/310 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.976); catalogued as COSV51559064; called by muse, mutect2, varscan2
- ALMS1 | c.4318C>T p.Q1440* | Nonsense Mutation (SNP) | VAF 22/230 reads (10%) | catalogued as COSV52519347; called by muse, mutect2, varscan2
- ALMS1 | c.11101C>T p.H3701Y | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as rs778698425, COSV52519356; called by muse, mutect2, varscan2
- CACNA1E | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 42/428 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62413359; called by muse, mutect2
- CDC42BPB | c.2712C>A p.N904K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.143); catalogued as COSV63476448; called by muse, mutect2, varscan2
- CEACAM4 | c.348C>A p.D116E | Missense Mutation (SNP) | VAF 98/543 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV55732219, COSV55732831; called by muse, mutect2, varscan2
- CFAP77 | c.667C>T p.R223W | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs182716958; called by muse, mutect2, varscan2
- CHM | c.403G>C p.D135H | Missense Mutation (SNP) | VAF 59/298 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV63303957; called by muse, mutect2, varscan2
- COL22A1 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV57355074; called by muse, mutect2, varscan2
- COMMD6 | c.54+1G>T p.X18_splice | Splice Site (SNP) | VAF 11/74 reads (15%) | catalogued as COSV63322728; called by muse, mutect2, varscan2
- CRYBG1 | c.4718+1G>T p.X1573_splice | Splice Site (SNP) | VAF 23/107 reads (21%) | catalogued as COSV64814062, COSV64815913; called by muse, mutect2, varscan2
- CUL7 | c.3007G>A p.D1003N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.248); catalogued as COSV54820904; called by muse, mutect2
- DNAH10 | c.9589G>A p.E3197K (on ENST00000409039; = p.E3136K on NM_207437.3) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as rs745751274, COSV68999630; called by muse, mutect2, varscan2
- DPEP2 | c.7C>A p.P3T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.053); catalogued as COSV52055850; called by muse, mutect2, varscan2
- EBF2 | c.346A>C p.S116R | Missense Mutation (SNP) | VAF 56/624 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV68780097; called by muse, mutect2
- ERICH3 | c.4237G>T p.E1413* | Nonsense Mutation (SNP) | VAF 36/271 reads (13%) | catalogued as COSV58615472; called by muse, mutect2, varscan2
- EXOC4 | c.1492G>T p.V498F | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.195); catalogued as COSV54113573, COSV54116589; called by muse, mutect2, varscan2
- GFM2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV57192911; called by muse, mutect2, varscan2
- GNRH2 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV55662205; called by muse, mutect2, varscan2
- GPX1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV101346303; called by muse, mutect2, varscan2
- GRAP2 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 63/240 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59996769; called by muse, mutect2, varscan2
- HDAC9 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.123); catalogued as COSV67782998; called by muse, varscan2
- IVNS1ABP | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as COSV62250273; called by muse, mutect2, varscan2
- KIAA1328 | c.1016G>C p.R339P | Missense Mutation (SNP) | VAF 66/430 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.284); catalogued as COSV54458460, COSV54458828, COSV54463000; called by muse, mutect2
- KRT33B | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.433); catalogued as COSV52442103, COSV99290761; called by muse, mutect2, varscan2
- KRT5 | c.1300G>T p.E434* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | catalogued as COSV52862911; called by muse, mutect2, varscan2
- KRTAP19-4 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.36); catalogued as COSV61859469; called by muse, mutect2, varscan2
- LTA4H | c.1349A>C p.Y450S | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV57384047; called by muse, mutect2, varscan2
- MAGEE2 | c.600G>A p.W200* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as rs773363908, COSV64897867; called by muse, mutect2, varscan2
- MC4R | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV55353024; called by muse, mutect2, varscan2
- MLST8 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV57030871; called by muse, mutect2, varscan2
- MTMR7 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as rs1397789228, COSV51669669; called by muse, mutect2, varscan2
- MUTYH | c.1559G>T p.R520L | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58344722, COSV58344865; called by muse, mutect2, varscan2
- MYH7 | c.3529del p.D1177Tfs*37 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | catalogued as COSV100805608; called by mutect2, varscan2
- NCOA3 | c.3877G>T p.D1293Y (on ENST00000371998 / NM_181659.3; = p.D1289Y on NM_006534.4) | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59072379; called by muse, mutect2, varscan2
- NECTIN2 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 52/234 reads (22%) | catalogued as COSV52979493; called by muse, mutect2, varscan2
- NEXN | c.1538T>A p.M513K | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53936881; called by muse, mutect2, varscan2
- OR14K1 | c.278T>A p.L93Q | Missense Mutation (SNP) | VAF 65/453 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.182); catalogued as COSV99315239; called by muse, mutect2, varscan2
- OR2T12 | c.637C>A p.L213M | Missense Mutation (SNP) | VAF 228/1456 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV58777121; called by muse, varscan2
- OTOP1 | c.844T>C p.S282P | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56396108; called by muse, mutect2, varscan2
- OVCH1 | c.2102C>A p.T701N | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58967160; called by muse, mutect2, varscan2
- PCDH11X | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.13); catalogued as rs761488640, COSV53438348; called by muse, mutect2, varscan2
- PCDHA11 | c.1352C>A p.A451E | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV56537323, COSV56541662; called by muse, mutect2
- PCLO | c.14798C>T p.P4933L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV61659325; called by muse, mutect2
- PFKP | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1313326199, COSV66900969; called by muse, mutect2, varscan2
- PHF12 | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52021644; called by muse, mutect2, varscan2
- PLA2G3 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 85/488 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV53212096; called by muse, mutect2, varscan2
- PLCD3 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV59562450; called by muse, mutect2, varscan2
- PPARGC1B | c.1496C>T p.P499L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as rs1312247542, COSV58532504; called by muse, mutect2, varscan2
- PPBP | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 48/214 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56020140; called by muse, mutect2, varscan2
- PPP2R2B | c.70A>G p.R24G | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV60775537; called by muse, mutect2
- RALGAPB | c.1832G>C p.R611P | Missense Mutation (SNP) | VAF 95/558 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53434481, COSV53439932; called by muse, mutect2, varscan2
- RESF1 | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 20/150 reads (13%) | catalogued as COSV57022191, COSV57024940; called by muse, mutect2, varscan2
- RSPH6A | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV55574565; called by muse, mutect2
- S100A7A | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 147/405 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61330802, COSV61331142; called by muse, mutect2, varscan2
- SACS | c.13259G>T p.C4420F | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs758721847, COSV66545665; called by muse, mutect2, varscan2
- SERPINB4 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as COSV61985969; called by muse, mutect2, varscan2
- SIMC1 | c.533G>T p.S178I (on ENST00000443967 / NM_001308196.1; = p.S197I on NM_001308195.2) | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV100365556; called by mutect2, varscan2
- SLC24A4 | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.331); catalogued as COSV54119696; called by muse, mutect2, varscan2
- SLC2A14 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 26/195 reads (13%) | catalogued as COSV61588202; called by muse, mutect2, varscan2
- SLC37A4 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); catalogued as rs782703235, COSV58156112; called by muse, mutect2, varscan2
- SLC6A11 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54397730; called by muse, mutect2, varscan2
- SLITRK6 | c.618C>A p.H206Q | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV68391361; called by muse, mutect2, varscan2
- SORCS3 | c.2029C>T p.L677F | Missense Mutation (SNP) | VAF 29/140 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.068); catalogued as COSV63797801; called by muse, mutect2, varscan2
- STAB1 | c.2885C>T p.A962V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV58741577; called by muse, mutect2, varscan2
- STK3 | c.976A>T p.M326L | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.02); catalogued as COSV69226286; called by muse, mutect2, varscan2
- SYT16 | c.1588A>T p.S530C | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70859029; called by muse, mutect2, varscan2
- TLR8 | c.2024T>C p.M675T (on ENST00000218032 / NM_138636.5; = p.M693T on NM_016610.4) | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54319923; called by muse, mutect2
- TRAPPC3 | c.42G>A p.M14I | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV64264557; called by muse, mutect2, varscan2
- TRIM49 | c.34del p.E12Nfs*8 | Frame Shift Del (DEL) | VAF 29/266 reads (11%) | catalogued as COSV100315860; called by mutect2, pindel, varscan2
- TSC2 | c.103C>T p.Q35* | Nonsense Mutation (SNP) | VAF 55/243 reads (23%) | catalogued as rs137854105, COSV54594080; ClinVar: not provided; called by muse, mutect2, varscan2
- TTBK1 | c.1553T>A p.V518E | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV52495477; called by muse, mutect2, varscan2
- TTN | c.41749G>T p.A13917S (on ENST00000591111; = p.A6493S on NM_003319.4) | Missense Mutation (SNP) | VAF 43/290 reads (15%) | PolyPhen probably damaging (0.996); catalogued as COSV60279341; called by muse, mutect2, varscan2
- USP19 | c.2002C>G p.P668A | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV60047949; called by muse, mutect2, varscan2
- VN1R2 | c.232T>G p.S78A | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV59039412; called by muse, mutect2, varscan2
- ZNF202 | c.793T>C p.Y265H | Missense Mutation (SNP) | VAF 13/238 reads (5%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.989); catalogued as COSV60248234; called by muse, mutect2
- ZNF202 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 10/118 reads (8%) | catalogued as COSV60248242; called by muse, mutect2
- ZNF324B | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60742924; called by muse, mutect2, varscan2
- ZNF407 | c.6184C>T p.P2062S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.554); catalogued as COSV55266194; called by muse, mutect2, varscan2
- ZP3 | c.449G>T p.S150I (on ENST00000394857 / NM_001110354.2; = p.S99I on NM_007155.6) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV60635093; called by muse, mutect2, varscan2
- LCOR | c.796del p.E266Sfs*14 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | called by mutect2, pindel, varscan2
- MSL1 | c.1633_1638del p.Q545_E546del (on ENST00000398532 / NM_001365919.1; = p.Q282_E283del on NM_001012241.2) | In Frame Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- TRO | c.2411_2441del p.S804Mfs*140 | Frame Shift Del (DEL) | VAF 47/154 reads (31%) | called by mutect2, pindel, varscan2
- AXIN2 | c.1984C>T p.L662= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as COSV100197102, COSV61060034; called by muse, mutect2, varscan2
- BCDIN3D | c.15G>T p.T5= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV61702779; called by muse, mutect2, varscan2
- CYFIP2 | c.2670G>T p.R890= (on ENST00000616178 / NM_001291722.2; = p.R865= on NM_014376.4) | Silent (SNP) | VAF 39/232 reads (17%) | catalogued as COSV56637850; called by muse, mutect2, varscan2
- GRHL2 | c.1095G>A p.A365= | Silent (SNP) | VAF 58/280 reads (21%) | catalogued as rs267601683, COSV52548750; called by muse, mutect2, varscan2
- KIF21A | c.2682G>C p.T894= (on ENST00000361418 / NM_001378440.1; = p.T881= on NM_017641.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/172 reads (20%) | catalogued as COSV62768358, COSV62776680; called by muse, mutect2, varscan2
- KMT2D | c.3489G>T p.V1163= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV56476202; called by muse, mutect2, varscan2
- LRRC4C | c.190C>A p.R64= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as COSV53421139, COSV53435466; called by muse, mutect2, varscan2
- MAST2 | c.1233G>A p.Q411= | Silent (SNP) | VAF 23/147 reads (16%) | catalogued as COSV63620852; called by muse, mutect2, varscan2
- MECOM | c.2196C>T p.R732= (on ENST00000468789 / NM_001105078.4; = p.R920= on NM_004991.4) | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as COSV52972206; called by muse, mutect2, varscan2
- MTMR4 | c.1077G>T p.V359= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as COSV60202778; called by muse, mutect2, varscan2
- MYO3B | c.2337G>T p.P779= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as COSV58711422, COSV58714238; called by muse, mutect2, varscan2
- OR2Z1 | c.750C>A p.L250= | Silent (SNP) | VAF 31/206 reads (15%) | catalogued as rs782149328, COSV60693130; called by muse, mutect2, varscan2
- OR4A15 | c.37T>C p.L13= | Silent (SNP) | VAF 33/208 reads (16%) | catalogued as COSV59037107; called by muse, mutect2, varscan2
- OR52R1 | c.99G>T p.P33= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV61887757, COSV61889205; called by muse, mutect2, varscan2
- OR5T2 | c.681T>G p.S227= | Silent (SNP) | VAF 85/608 reads (14%) | catalogued as COSV57588476, COSV57589308, COSV57590451; called by muse, mutect2, varscan2
- OR7D4 | c.597G>A p.L199= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs377419980, COSV58072318; called by muse, mutect2, varscan2
- PCDHA11 | c.1683G>A p.A561= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV56537339; called by muse, mutect2, varscan2
- PRKCQ | c.2097C>A p.P699= | Silent (SNP) | VAF 36/190 reads (19%) | catalogued as COSV54117359; called by muse, mutect2, varscan2
- RYR1 | c.4842G>A p.V1614= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV62102285; called by muse, mutect2, varscan2
- SPIN4 | c.75C>T p.H25= | Silent (SNP) | VAF 39/77 reads (51%) | catalogued as COSV58738458; called by muse, mutect2, varscan2
- SPON1 | c.1608C>G p.S536= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as COSV100115985; called by muse, mutect2
- ZGPAT | c.129G>T p.L43= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV60833189; called by muse, mutect2, varscan2
- ZNF154 | c.102T>A p.A34= | Silent (SNP) | VAF 26/240 reads (11%) | catalogued as COSV70745376; called by muse, mutect2, varscan2
- ZNF536 | c.579C>T p.R193= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV62821165, COSV62836290; called by muse, mutect2, varscan2
- ESPN | chr1:6460106 G>T | 3'Flank (SNP) | VAF 35/179 reads (20%) | catalogued as rs761979450, COSV61069418, COSV61069475; called by muse, mutect2, varscan2
- TMPRSS3 | c.952+16T>C | Intron (SNP) | VAF 14/149 reads (9%) | catalogued as COSV52306725; called by muse, mutect2
